Gene-level copy-number profile of tumor specimen TCGA-VS-A8Q9-01A from TCGA case TCGA-VS-A8Q9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 79.1 years (28,881 days).
Specimen TCGA-VS-A8Q9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.bb6746e5-effc-46fa-8da2-13d813de6047.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8Q9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e066ebd4-817f-4332-b605-c53571596898

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 11,655; copy number 2: 42,258; copy number 3: 5,226; copy number 4: 231; copy number 5: 54; copy number 6: 78; copy number 8: 57; copy number 9: 42; copy number 10: 103; copy number 12: 23; copy number 14: 68; copy number 15: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8Q9-01A-12D-A37M-01): tumor purity 0.54, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:30,830,369–31,369,810, 3 genes (within-gene range 0–1): DCDC1, CYCSP25, AL137804.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 436 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:31,981,750–35,256,946, 53 genes, copy number 5: ZNF860, RPL21P40, AC094019.1, Y_RNA, NIFKP7, GPD1L, AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P.
- chr3:35,650,197–35,651,961, 1 gene, copy number 5: ARPP21-AS1.
- chr11:36,269,284–36,697,867, 11 genes, copy number 15: COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr11:42,939,775–48,328,471, 156 genes, copy number 8–10 (broad region; genes not listed).
- chr11:69,481,662–71,818,238, 64 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr11:101,451,564–101,872,562, 1 gene, copy number 8 (within-gene range 1–8): TRPC6.
- chr11:101,765,935–103,479,863, 49 genes, copy number 8–14: AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr19:10,718,079–10,833,488, 1 gene, copy number 6 (within-gene range 4–6): DNM2.
- chr19:10,780,254–11,133,820, 15 genes, copy number 6 (within-gene range 4–6): MIR4748, MIR199A1, MIR6793, TMED1, C19orf38, HIKESHIP2, CARM1, YIPF2, TIMM29, SMARCA4, AC011442.1, RN7SL192P, AC006127.1, LDLR, MIR6886.
- chr19:12,763,003–12,872,740, 1 gene, copy number 12 (within-gene range 2–12): HOOK2.
- chr19:12,796,820–12,957,223, 22 genes, copy number 12: PRDX2, AC018761.2, THSD8, RNASEH2A, RTBDN, AC020934.1, MAST1, MIR6794, DNASE2, AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1.
- chr19:43,401,496–44,529,788, 62 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,655. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
